Somatic mutation profile of tumor specimen MP2PRT-PATBCP-TMP1-A (aliquot MP2PRT-PATBCP-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATBCP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,275 days).
Specimen MP2PRT-PATBCP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd3b404b-81e6-46c4-a594-07455702d92e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBCP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBCP-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc2504b4-eb1c-46bd-9c31-840077ac5455

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 60/161 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CILP2 | c.2282C>T p.T761M | Missense Mutation (SNP) | VAF 121/644 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs762122624, COSV52277383; called by muse, varscan2
- DDI1 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs1288574029, COSV56368807; called by muse, mutect2, varscan2
- FAAH2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200667637, COSV100887191; called by muse, mutect2, varscan2
- FAT4 | c.13898C>T p.S4633L | Missense Mutation (SNP) | VAF 162/565 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771288110, COSV58674300, COSV58674409; called by muse, varscan2
- NLRP11 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as rs749940136, COSV64087300; called by muse, mutect2, varscan2
- USP1 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51998352; called by muse, mutect2, varscan2
- AL592490.1 | c.308C>G p.S103W | Missense Mutation (SNP) | VAF 233/624 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBLIF | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 79/229 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL4A3 | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 154/342 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- THTPA | c.399G>C p.L133F | Missense Mutation (SNP) | VAF 134/380 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.533A>T p.D178V | Missense Mutation (SNP) | VAF 119/303 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- CACNA2D1 | c.1395G>A p.P465= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as rs746665546, COSV62388622; called by muse, mutect2, varscan2
- CRYBG1 | c.3054A>T p.T1018= | Silent (SNP) | VAF 159/538 reads (30%) | called by muse, mutect2, varscan2
- HMCN2 | c.15057C>T p.G5019= | Silent (SNP) | VAF 239/676 reads (35%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.1545C>T p.T515= | Silent (SNP) | VAF 118/447 reads (26%) | called by muse, mutect2, varscan2
- RYR1 | c.5475C>T p.H1825= | Silent (SNP) | VAF 182/445 reads (41%) | catalogued as rs747310543, COSV100616906, COSV62095399; called by muse, mutect2, varscan2
- SEMA3D | c.1104T>C p.V368= | Silent (SNP) | VAF 123/273 reads (45%) | called by muse, mutect2, varscan2
- ANKRD18A | chr9:38571175 G>T | 3'Flank (SNP) | VAF 130/378 reads (34%) | called by muse, mutect2
